MMRF case MMRF_1520 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d501e20b-a774-4362-917d-cbde9cbbd6c5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.4 years (22,782 days); ISS stage: I; Days to last known disease status: 1,260 days (3.4 years); Days to last follow up: 1,260 days (3.4 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 71 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 149 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 150 days; Days to treatment end: 150 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days; Days to treatment end: 414 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 281 days; Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 414 days (1.1 years); Days to treatment end: 442 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 442 days (1.2 years); Days to treatment end: 607 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 442 days (1.2 years); Days to treatment end: 980 days (2.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,204 days (3.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 5.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.565 mg/dL; Immunoglobulin G 56 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 4.84 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 11.6 g/dL; Glucose 4.9 mmol/L; C-Reactive Protein 0.7 mg/dL.
- Day 85 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.192 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.853 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.45 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.93 mmol/L.
- Day 164 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.127 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.179 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 4.92 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 8.38 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 253 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.581 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.487 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.59 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.
- Day 330 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.109 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.478 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 5.03 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.12 mmol/L.
- Day 442 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0276 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.486 mg/dL; Immunoglobulin G 5.48 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.28 mmol/L.
- Day 533 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.141 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.151 mg/dL; Immunoglobulin G 6.72 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 617 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0276 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.156 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.73 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.
- Day 701 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.856 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.724 mg/dL; Immunoglobulin G 6.68 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.22 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.06 mmol/L.
- Day 785 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.928 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.807 mg/dL; Immunoglobulin G 8.15 g/L; Immunoglobulin A 0.65 g/L; Immunoglobulin M 0.25 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 896 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.32 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 980 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.884 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.795 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.55 ×10⁹/L; Platelets 254 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 6.27 mmol/L.
- Day 1,057 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.612 mg/dL; Immunoglobulin G 7.81 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.25 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.01 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 7.81 mmol/L.
- Day 1,169 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.0302 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.112 mg/dL; Immunoglobulin G 3.31 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.09 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 8.8 g/dL; Glucose 6.66 mmol/L.
- Day 1,260 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.939 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.618 mg/dL; Immunoglobulin G 5.78 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 6.93 mmol/L.

Other clinical attributes
- Day -18: Weight: 91 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1520_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1520_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
- Sample MMRF_1520_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 253 days.
